TCGA case TCGA-19-1786 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Case Western. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d6830f6f-7bd5-4d43-81bd-42c64a73dd8b

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 64.5 years (23,568 days); Year of diagnosis: 2008; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 45 days; Days to treatment end: 92 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 218 days; Disease response: Tumor Free.
- Karnofsky performance status: 40.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-19-1786-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.1; Intermediate dimension: 0.8; Shortest dimension: 0.5.
  Slide TCGA-19-1786-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 35; Percent stromal cells: 5.
  Slide TCGA-19-1786-01A-01-BS1: Section location: Bottom; Percent tumor cells: 65; Percent tumor nuclei: 80; Percent normal cells: 10; Percent necrosis: 25; Percent stromal cells: 5.
- Sample TCGA-19-1786-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-19-1786-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: Tumor free; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 218 days; disease-specific survival: no event (censored), 218 days; progression-free interval: no event (censored), 218 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-19-1786-01A-01D-0591-01): tumor purity 0.87, ploidy 2.06, whole-genome doublings 0.
